Somatic mutation profile of tumor specimen TCGA-CM-6163-01A (aliquot TCGA-CM-6163-01A-11D-1650-10) from TCGA case TCGA-CM-6163, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 74.3 years (27,150 days).
Specimen TCGA-CM-6163-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01fd1440-702e-49d7-ad6b-bfe256526982.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6163-10A (Blood Derived Normal), aliquot TCGA-CM-6163-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51c832ec-c4cd-49d3-956b-fe5a013ac0af

The open-access MAF lists 106 somatic variants for this specimen: 78 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 27, Nonsense Mutation 9, Splice Site 3, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 83/176 reads (47%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.3717+1G>A p.X1239_splice | Splice Site (SNP) | VAF 42/140 reads (30%) | catalogued as rs748706627, CS084911, CS1110183, COSV57267115, COSV57354933, COSV57355539; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 21/69 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WDR45 | c.397C>T p.R133* (on ENST00000376372 / NM_001029896.2; = p.R134* on NM_007075.3) | Nonsense Mutation (SNP) | VAF 50/66 reads (76%) | catalogued as rs797046101, CM1211565, COSV59876454; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACBD5 | c.1220G>C p.R407T (on ENST00000375888 / NM_001352568.1; = p.R398T on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101022560; called by muse, mutect2
- ADAR | c.3392C>T p.A1131V | Missense Mutation (SNP) | VAF 42/315 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99426147; called by muse, mutect2, varscan2
- AKAP11 | c.2534G>A p.G845D | Missense Mutation (SNP) | VAF 69/237 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV50298945; called by muse, mutect2, varscan2
- ALOX15B | c.1331G>A p.R444K | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.116); catalogued as rs1163271134, COSV101205626; called by muse, mutect2
- APP | c.1475A>G p.N492S | Missense Mutation (SNP) | VAF 116/236 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.051); catalogued as rs769638062, COSV61001608; called by muse, mutect2, varscan2
- ATP7A | c.2718T>A p.H906Q | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV58450378; called by muse, mutect2
- BCAS3 | c.994-1G>C p.X332_splice | Splice Site (SNP) | VAF 115/354 reads (32%) | catalogued as COSV66778114; called by muse, mutect2, varscan2
- CACNA1F | c.2933G>A p.R978Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1246493051, COSV59905767; called by muse, mutect2, varscan2
- CIC | c.3640C>T p.R1214* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as rs968289754, COSV50569160; called by muse, mutect2, varscan2
- COL5A1 | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.284); catalogued as rs757893904, COSV65672255; called by muse, mutect2, varscan2
- CRISPLD1 | c.924C>A p.C308* | Nonsense Mutation (SNP) | VAF 49/626 reads (8%) | catalogued as COSV100082083; called by muse, mutect2
- CSPG5 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV99273853; called by muse, mutect2
- DCAF6 | c.1834G>C p.D612H (on ENST00000312263 / NM_001349778.1; = p.D632H on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/375 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.26); catalogued as COSV100394747, COSV56581994; called by muse, mutect2, varscan2
- DIS3 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 170/449 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369590515; called by muse, mutect2, varscan2
- DMD | c.2530C>A p.Q844K | Missense Mutation (SNP) | VAF 122/197 reads (62%) | SIFT tolerated (0.52); PolyPhen benign (0.155); catalogued as rs768892830, COSV63775897; called by muse, mutect2, varscan2
- DNAH5 | c.7484C>T p.A2495V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs768364281, COSV54240172; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUSP11 | c.628A>C p.I210L | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV99731087; called by muse, mutect2, varscan2
- ECHDC2 | c.668G>A p.R223Q (on ENST00000371522 / NM_001198961.2; = p.R192Q on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs754843817, COSV64301835, COSV64302444; called by muse, mutect2, varscan2
- EIF6 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.192); catalogued as COSV55771787; called by muse, mutect2, varscan2
- EP300 | c.2269C>T p.Q757* | Nonsense Mutation (SNP) | VAF 68/205 reads (33%) | catalogued as COSV99608784; called by muse, mutect2, varscan2
- ERBB4 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs765191737, COSV53499598; called by muse, mutect2, varscan2
- FTO | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as rs531215275, COSV67113014; ClinVar: uncertain significance; called by muse, varscan2
- FUT8 | c.981G>A p.W327* (on ENST00000360689 / NM_001371534.1; = p.W164* on NM_004480.4) | Nonsense Mutation (SNP) | VAF 16/113 reads (14%) | catalogued as COSV61288164; called by muse, mutect2, varscan2
- G6PD | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 47/66 reads (71%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs150589041, COSV63703821; called by muse, mutect2, varscan2
- GAA | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV56410014; called by muse, mutect2, varscan2
- GAK | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.909); catalogued as rs139900404; called by muse, mutect2, varscan2
- GIGYF2 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV65248163; called by muse, mutect2, varscan2
- H3C3 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV63551288; called by muse, mutect2, varscan2
- HRNR | c.6254G>T p.G2085V | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.767); catalogued as rs781019927, COSV100913552; called by muse, mutect2, varscan2
- HTR2C | c.79G>T p.V27L | Missense Mutation (SNP) | VAF 24/516 reads (5%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.056); catalogued as COSV99349613; called by muse, mutect2
- KCNQ2 | c.2119G>A p.A707T (on ENST00000359125 / NM_172107.4; = p.A679T on NM_004518.6) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs543477138, COSV60544464; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KIR2DL3 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as rs755633828; called by muse, mutect2, varscan2
- KLF5 | c.293C>G p.P98R | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV66615010; called by muse, mutect2
- KLHL30 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.687); catalogued as rs773445797, COSV59977332; called by muse, mutect2, varscan2
- KRT6B | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 79/319 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.315); catalogued as rs756538750, COSV52881720; called by muse, mutect2, varscan2
- LAMA4 | c.2002G>A p.E668K (on ENST00000230538 / NM_001105206.3; = p.E661K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/249 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.108); catalogued as rs781920228, COSV57901582; called by muse, mutect2, varscan2
- LDOC1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as COSV65159510; called by muse, mutect2, varscan2
- MC3R | c.500C>A p.A167D | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as COSV54764457, COSV99710810; called by muse, mutect2, varscan2
- MGAT4C | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs147418986; called by muse, mutect2, varscan2
- MINPP1 | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 82/398 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV64354772; called by muse, mutect2, varscan2
- MLYCD | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs377566911, COSV52305337; called by muse, mutect2, varscan2
- MNS1 | c.1269+1G>A p.X423_splice | Splice Site (SNP) | VAF 113/236 reads (48%) | catalogued as COSV53069439; called by muse, mutect2, varscan2
- MTMR8 | c.164T>C p.I55T | Missense Mutation (SNP) | VAF 165/240 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66395262; called by muse, mutect2, varscan2
- MYO3A | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs148453072, COSV56340043; called by muse, mutect2
- NBEA | c.468A>C p.E156D | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as COSV100076744; called by muse, mutect2
- NCKAP5 | c.1768G>T p.E590* | Nonsense Mutation (SNP) | VAF 14/106 reads (13%) | catalogued as COSV58461275; called by muse, mutect2, varscan2
- NDE1 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.882); catalogued as rs1232186532, COSV100707087, COSV61274355; called by muse, mutect2, varscan2
- OR2M3 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 224/529 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs967288368, COSV101513523, COSV71759188; called by muse, mutect2, varscan2
- OTOL1 | c.1296C>G p.I432M | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as COSV100020033, COSV60008615; called by muse, mutect2
- PACRG | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777419437, COSV100434344, COSV61311519; called by muse, mutect2, varscan2
- PAX3 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.302); catalogued as rs770087251, CD102011, COSV60586905; called by muse, mutect2, varscan2
- PCDH9 | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100121290; called by muse, mutect2
- PCDHB6 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.629); catalogued as COSV50709369; called by muse, mutect2, varscan2
- PFKP | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66899848; called by muse, mutect2, varscan2
- PSG11 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 69/195 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as rs527275238, COSV60453877; called by muse, mutect2, varscan2
- RAB11FIP3 | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51930223; called by muse, mutect2, varscan2
- SCN7A | c.4726G>A p.D1576N | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs372024247, COSV69273190; called by muse, mutect2, varscan2
- SLC9A5 | c.2691G>C p.*897Yext*22 | Nonstop Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100237357; called by muse, mutect2
- SMARCC2 | c.2211C>A p.S737R | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV57221780; called by muse, mutect2, varscan2
- SNIP1 | c.282T>G p.S94R | Missense Mutation (SNP) | VAF 227/479 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.055); catalogued as COSV56167536; called by muse, mutect2, varscan2
- SPANXD | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 573/954 reads (60%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.992); catalogued as rs199908821, COSV65152611; called by muse, mutect2, varscan2
- STC2 | c.745C>A p.P249T | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV54179402, COSV54181121; called by muse, mutect2, varscan2
- SYCP2L | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV99305284; called by muse, mutect2
- TEX11 | c.833G>T p.W278L (on ENST00000344304; = p.W263L on NM_031276.3) | Missense Mutation (SNP) | VAF 156/388 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.807); catalogued as COSV60226454, COSV60235007; called by muse, mutect2, varscan2
- TFEB | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.358); catalogued as rs1473263334, COSV100026243; called by muse, mutect2
- TIGD3 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs142471374; called by muse, mutect2, varscan2
- TMEM104 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769979376, COSV59109425; called by muse, mutect2, varscan2
- TRIM17 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757591425, COSV52858987; called by muse, mutect2, varscan2
- TRIM54 | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56084622; called by muse, mutect2
- TUBGCP2 | c.2476G>A p.D826N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as COSV53307145; called by muse, mutect2, varscan2
- UROC1 | c.1648G>A p.G550S | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373958192; called by muse, mutect2, varscan2
- WDR86 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.129); catalogued as rs753850081, COSV57842262; called by muse, mutect2, varscan2
- WRN | c.4003A>G p.I1335V | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.365); catalogued as COSV53303962; called by muse, mutect2, varscan2
- ZNF536 | c.1699G>A p.V567M | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV62821277; called by muse, mutect2, varscan2
- ADAMTS15 | c.534G>A p.S178= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV54507940; called by muse, mutect2, varscan2
- AR | c.1122G>A p.P374= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV65960720; called by muse, mutect2, varscan2
- CHTOP | c.378A>G p.L126= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV64155004; called by muse, mutect2, varscan2
- COL4A1 | c.4875C>T p.Y1625= | Silent (SNP) | VAF 51/118 reads (43%) | catalogued as rs148750080; called by muse, mutect2, varscan2
- CRY1 | c.336T>C p.A112= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as COSV50486552; called by muse, mutect2, varscan2
- DYSF | c.5538C>T p.G1846= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as rs1237109693, COSV99247658; called by muse, varscan2
- FAM50B | c.108C>T p.A36= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs530034568, COSV66654997; called by muse, mutect2
- H3C4 | c.267G>T p.A89= | Silent (SNP) | VAF 58/143 reads (41%) | catalogued as COSV61912174; called by muse, mutect2, varscan2
- HCK | c.405C>T p.R135= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as rs913095249, COSV52941773; called by muse, mutect2, varscan2
- HOXC10 | c.12T>A p.P4= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs771375837, COSV57726757; called by muse, mutect2, varscan2
- IFT43 | c.495C>T p.H165= (on ENST00000314067 / NM_001102564.3; = p.H170= on NM_052873.3) | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs374896158; called by muse, mutect2, varscan2
- IQCK | c.303G>A p.P101= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as rs769969486, COSV57525400; called by muse, mutect2, varscan2
- KRT7 | c.699G>A p.L233= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as rs745420332, COSV59332057; called by muse, mutect2, varscan2
- LIN37 | c.360C>T p.R120= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs371307158; called by muse, mutect2, varscan2
- LRP5 | c.2727C>T p.N909= | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- MYH8 | c.4494C>T p.L1498= | Silent (SNP) | VAF 40/182 reads (22%) | catalogued as rs767692982, COSV67969173; called by muse, mutect2, varscan2
- NLGN1 | c.546C>A p.G182= | Silent (SNP) | VAF 50/258 reads (19%) | catalogued as COSV64341190; called by muse, mutect2, varscan2
- PLXNA2 | c.1347G>T p.G449= | Silent (SNP) | VAF 11/191 reads (6%) | catalogued as COSV100885558; called by muse, mutect2
- PPP2R5D | c.867C>T p.Y289= | Silent (SNP) | VAF 51/136 reads (38%) | catalogued as rs759229882, COSV99776467; called by muse, mutect2, varscan2
- RGS12 | c.1230C>T p.A410= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs756319302, COSV60907878; called by muse, mutect2, varscan2
- RTL3 | c.1269G>A p.Q423= | Silent (SNP) | VAF 101/154 reads (66%) | catalogued as COSV100329603, COSV100329840; called by muse, mutect2, varscan2
- SIDT1 | c.681C>T p.L227= | Silent (SNP) | VAF 46/132 reads (35%) | catalogued as rs141350402; called by muse, mutect2, varscan2
- SLC6A19 | c.1605C>T p.R535= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs769158869, COSV57251423, COSV57251734; called by muse, mutect2, varscan2
- TIMD4 | c.513C>T p.V171= | Silent (SNP) | VAF 674/2271 reads (30%) | catalogued as rs747523800, COSV50856516, COSV50857517; called by muse, mutect2, varscan2
- TMEM132E | c.2496G>A p.P832= (on ENST00000321639; = p.P922= on NM_001304438.2) | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs1055075415, COSV58699045; called by muse, mutect2, varscan2
- TTN | c.95553A>G p.P31851= (on ENST00000591111; = p.P24427= on NM_003319.4) | Silent (SNP) | VAF 97/350 reads (28%) | catalogued as COSV60202386; called by muse, mutect2, varscan2
- ZNF776 | c.1359C>T p.I453= | Silent (SNP) | VAF 39/137 reads (28%) | catalogued as COSV57814529; called by muse, mutect2, varscan2
- SIRT5 | c.857+3538C>T | Intron (SNP) | VAF 18/256 reads (7%) | catalogued as COSV63081373; called by muse, mutect2
